Somatic mutation profile of tumor specimen TARGET-30-PAUKAP-01A (aliquot TARGET-30-PAUKAP-01A-01D) from TARGET case TARGET-30-PAUKAP, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.5 years (1,273 days).
Specimen TARGET-30-PAUKAP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 790dfab4-9d0e-4a8f-b2d7-8bfbcbf46f2b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUKAP-10A (Blood Derived Normal), aliquot TARGET-30-PAUKAP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4299587a-c58f-4226-9f4a-cb2d9492c936

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRXN1 | c.2376C>A p.S792R | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.845); catalogued as COSV58445057; called by muse, mutect2, varscan2
- PCLO | c.6844G>C p.E2282Q | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.054); catalogued as COSV61646039; called by muse, mutect2, varscan2
- ARID1A | c.4225_4235dup p.A1413Sfs*72 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | called by mutect2, varscan2
